Surgical pathology report (de-identified scan), TCGA case TCGA-5M-AATA, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Sao Paulo, specimen TCGA-5M-AATA-01A (Primary Tumor).

CLF
ICD-O-3
Adenocarcinoma NOS 8140/3
Adenocarcinoma, tubular 8211/3
Site: Sigmoid colon C18.7
QJ 5/21/14

Date:

SPECIMEN: Sigmoid colon, rectum, anal canal

PROCEDURE: Excision of the rectum and anal canal

MACROSCOPY

- Two bottles were received.

Bottle #1 – Identification: "Rectosigmoid, rectum, anal canal"

- Segment of large intestine measuring 65.0 cm in length and 4.0 cm in median diameter.
- An ulcerated lesion measuring 8.0 x 3.2 cm and 1.6 cm thick can be found in the mucosa less than 0.5 cm of the presumed distal margin.
- Another segment previously opened along its greater axis measuring 5.2 cm in length and 3.6 cm in diameter was assumed to be the rectum, and displayed no grossly pathologic features.
- A nodular, indurated structure measuring 1.6 x 0.6 x 0.3 cm was dissected from the segment of colon.

Bottle #2 – Identification: "Polyp"

- Fragment of pale, soft, irregular tissue measuring 0.3 x 0.2 x 0.2 cm.

MICROSCOPIC EXAMINATION

Bottle #1

- Moderately differentiated tubular adenocarcinoma;
- Microscopic tumor extension: tumor penetrates to the subserosa;
- Perineural invasion: not observed;
- Lymph-vascular invasion: not observed;
- Moderate desmoplastic stromal reaction, mild intratumoral and peritumoral inflammatory infiltrate.
- Surgical margins free of neoplastic involvement;
- Number of lymph nodes examined: 5;
- Number of lymph nodes involved: 2;
- Stage: pT3 pN1

Bottle #2

- Tubular adenoma with low grade epithelial dysplasia.

PATHOLOGISTS

Source: NCI Genomic Data Commons file ff829992-12bd-4e9f-9cb6-9e20c39c92db (TCGA-5M-AATA.9EC72159-5123-48AD-BBBC-DF2F1B6FAF3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).